Somatic mutation profile of tumor specimen 0DJVPH from CCDI case PBBXKI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.3 years (2,287 days).
Specimen 0DJVPH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76dbe394-6e77-47a5-855c-b1a2691cc9dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJVPC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c4515bf-f2ee-4e9d-90d2-4969f9c0b1ae

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 20/522 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs767397757, COSV58228252; called by muse, mutect2
- BX276092.9 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 12/261 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs1031595281; called by muse, mutect2
- TUBB8B | c.36C>A p.C12* | Nonsense Mutation (SNP) | VAF 26/217 reads (12%) | catalogued as COSV58265910; called by muse, mutect2
- ARHGAP4 | c.1476C>A p.R492= | Silent (SNP) | VAF 33/868 reads (4%) | called by muse, mutect2
- LAMA2 | c.7638A>G p.V2546= | Silent (SNP) | VAF 96/1987 reads (5%) | called by muse, mutect2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 52/2200 reads (2%) | called by muse, mutect2
- DPM3 | c.-32+85G>C | Intron (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
